Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A677, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A677-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: In bladder, there are an invasive tumor, ill - margins with 3x2x2cm in size, soft and gray surface.

Microscopic Description: Transitional cells are hyperplastic. Tumor cells arrange to form papillary or trabeculae. Tumor cells have moderate and eosinophilic cytoplasm. Nuclei are enlarged and variability in shape and size, very irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in deeply muscularis propria.

Diagnosis Details: Infiltrating urothelial carcinoma, low-grade, infiltrating outer half muscularis propria

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 3 x 2 x 2 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Muscularis propria

Lymph nodes: Not specified

Lymphatic invasion: Absent

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

O&F path Carcinoma, transitional cell, papillary NOS 8130/3
Site: Bladder NOS C67.9
Jw 5/16/13

Source: NCI Genomic Data Commons file dce35f57-bc55-4401-81f7-8018794c547f (TCGA-E7-A677.C721E01B-0C35-41AE-952C-5D2AB8373BC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).